Somatic mutation profile of tumor specimen TCGA-95-8494-01A (aliquot TCGA-95-8494-01A-11D-2323-08) from TCGA case TCGA-95-8494, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.8 years (24,773 days).
Specimen TCGA-95-8494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9b92c52-a0ac-4297-956c-6af61c63d87a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-8494-10A (Blood Derived Normal), aliquot TCGA-95-8494-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5238aa5-5e5b-4437-afe4-d1c76b47bae7

The open-access MAF lists 114 somatic variants for this specimen: 76 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 35, Nonsense Mutation 6, Frame Shift Del 1, RNA 1, 3'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.1320C>G p.F440L | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99491434; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1552C>G p.P518A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs777478615, COSV99718610; called by muse, mutect2, varscan2
- AHCYL2 | c.1411A>T p.N471Y | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV61488804; called by muse, mutect2, varscan2
- AHI1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs1171941077, COSV99662632; called by muse, mutect2, varscan2
- AL136295.1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as COSV99841705; called by muse, mutect2, varscan2
- ALDH3A1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV56734995; called by muse, mutect2, varscan2
- ARFGEF1 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51613922, COSV99142193; called by muse, mutect2, varscan2
- ARHGAP11A | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV100853233; called by muse, mutect2, varscan2
- ATP10B | c.3562G>C p.E1188Q | Missense Mutation (SNP) | VAF 75/557 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100514849; called by muse, mutect2, varscan2
- B3GNT3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as rs769887503, COSV100427574; called by muse, mutect2, varscan2
- B4GALT5 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430069480, COSV100867001, COSV99056823; called by muse, mutect2, varscan2
- BCL6 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.921); catalogued as rs142220629; called by muse, mutect2, varscan2
- BDP1 | c.4786G>A p.E1596K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs750411430, COSV100703022; called by muse, mutect2, varscan2
- BTBD11 | c.1648G>A p.D550N (on ENST00000280758 / NM_001018072.2; = p.D87N on NM_001017523.2) | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1428243063, COSV99775572; called by muse, mutect2, varscan2
- CDH9 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); catalogued as COSV50267140, COSV50280435; called by muse, mutect2
- CEACAM4 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV55731820; called by muse, mutect2, varscan2
- CLEC5A | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV101407766; called by muse, mutect2
- CLIP1 | c.1715C>G p.S572C (on ENST00000620786 / NM_001247997.1; = p.S561C on NM_002956.2) | Missense Mutation (SNP) | VAF 71/440 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100211636, COSV56803275, COSV56805181; called by muse, mutect2, varscan2
- EHD3 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.166); catalogued as rs372292180; called by muse, mutect2, varscan2
- EOMES | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99841927, COSV99842089; called by muse, mutect2
- EPB41L4A | c.813C>G p.F271L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs771551149, COSV99813287; called by muse, mutect2, varscan2
- EPG5 | c.6050A>G p.D2017G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1309399920, COSV99957153; called by muse, mutect2, varscan2
- EPPK1 | c.5773G>T p.A1925S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV101599828; called by muse, mutect2, varscan2
- EVPL | c.3023A>T p.K1008M | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV100044447; called by muse, mutect2, varscan2
- EVPL | c.2569G>T p.E857* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100044449; called by muse, mutect2, varscan2
- FANCL | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV99287483; called by muse, mutect2, varscan2
- FAT3 | c.8773G>A p.A2925T | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.108); catalogued as rs745373906, COSV53085882; called by muse, mutect2, varscan2
- FCRL2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs764532671, COSV100829833, COSV63835060; called by muse, mutect2, varscan2
- FGF18 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV99208977; called by muse, mutect2, varscan2
- GALNT13 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as COSV101222852; called by muse, mutect2
- GCC2 | c.3447A>C p.K1149N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100565426; called by muse, mutect2, varscan2
- GOLGA2 | c.1184G>A p.W395* | Nonsense Mutation (SNP) | VAF 23/140 reads (16%) | catalogued as COSV101363118; called by muse, mutect2, varscan2
- GPR21 | c.380G>C p.R127T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101016436; called by muse, mutect2, varscan2
- GPX8 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99696866; called by muse, mutect2, varscan2
- HTR3A | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs377539661; called by muse, mutect2, varscan2
- IDH1 | c.305T>C p.I102T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs1226814453, COSV61626228; called by muse, mutect2, varscan2
- KIF4A | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV100979497; called by muse, mutect2, varscan2
- LAMC2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs770562490, COSV99917398; called by muse, mutect2, varscan2
- MCM4 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs755169604, COSV100031502; called by muse, mutect2, varscan2
- MICAL2 | c.2661T>G p.N887K | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV99817355; called by muse, mutect2, varscan2
- MPHOSPH8 | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV100825089; called by muse, mutect2
- MRPL11 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); catalogued as rs377543470; called by muse, mutect2, varscan2
- MYEF2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV51046072, COSV99981569; called by muse, mutect2
- MYH4 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs149818821; called by muse, mutect2, varscan2
- MZB1 | c.557G>C p.R186T | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV56172048; called by muse, mutect2, varscan2
- NBPF1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 55/410 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV101236440; called by muse, mutect2, varscan2
- NOTUM | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1312771441, COSV101293747, COSV101293757; called by muse, mutect2, varscan2
- OGDHL | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934290; called by muse, mutect2, varscan2
- PCDHGA3 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.235); catalogued as rs1487000938, COSV99534898; called by muse, mutect2
- PHTF2 | c.1153C>T p.R385C (on ENST00000248550 / NM_001366089.1; = p.R347C on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs199608889, COSV99301641; called by muse, mutect2, varscan2
- PLD1 | c.2688C>A p.H896Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100578101; called by muse, mutect2, varscan2
- PLD5 | c.979G>C p.D327H (on ENST00000442594; = p.D265H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV100140188; called by muse, mutect2, varscan2
- PLEKHA5 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as rs561325872, COSV100163973; called by muse, mutect2, varscan2
- PLPPR4 | c.1328G>C p.R443P | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100926791, COSV64568024; called by muse, mutect2, varscan2
- RALB | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55603155, COSV55604583; called by muse, mutect2, varscan2
- ROPN1 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); catalogued as COSV99481350; called by mutect2, varscan2
- SFMBT1 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99966059; called by muse, mutect2, varscan2
- SI | c.5141C>T p.A1714V | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100015348; called by muse, mutect2, varscan2
- SLC19A3 | c.1072G>A p.G358S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs758563802, COSV99295818; called by muse, mutect2, varscan2
- SLCO6A1 | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs547449839, COSV101133668, COSV101134284; called by muse, mutect2
- ST3GAL2 | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 15/202 reads (7%) | PolyPhen probably damaging (0.997); catalogued as COSV100735655; called by muse, mutect2
- STAT4 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 20/161 reads (12%) | catalogued as rs1252710156; called by muse, mutect2, varscan2
- SVIL | c.4348+2T>A p.X1450_splice (on ENST00000355867 / NM_021738.3; = p.X1024_splice on NM_003174.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100881236; called by muse, mutect2, varscan2
- TCP11L2 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs375276250; called by muse, mutect2, varscan2
- THSD7A | c.2199G>C p.Q733H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101448690; called by muse, mutect2
- TLL2 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs563536531, COSV100780266; called by muse, mutect2, varscan2
- TMTC1 | c.1073T>A p.I358N (on ENST00000539277 / NM_001193451.2; = p.I250N on NM_175861.3) | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV99758373, COSV99759546; called by muse, mutect2, varscan2
- TNN | c.1700C>G p.S567C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53431517; called by muse, mutect2, varscan2
- TTN | c.24986G>A p.R8329H (on ENST00000591111; = p.R7402H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | PolyPhen benign (0); catalogued as rs144587343; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- XIRP2 | c.3706G>A p.D1236N (on ENST00000628543; = p.D1411N on NM_152381.6) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.782); catalogued as COSV54693241, COSV99742426; called by muse, mutect2, varscan2
- ZAN | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 246/689 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as rs777283469, COSV100769668; called by muse, mutect2, varscan2
- ZFAND2B | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as COSV99202408; called by muse, mutect2, varscan2
- CPEB1 | c.1799G>C p.C600S (on ENST00000617958; = p.C535S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STEAP3 | c.590C>A p.S197* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- TNS3 | c.3960_3973del p.E1320Dfs*89 | Frame Shift Del (DEL) | VAF 50/112 reads (45%) | called by mutect2, pindel, varscan2
- APC2 | c.3798G>A p.E1266= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1164449712, COSV52020877; called by muse, mutect2, varscan2
- BNC2 | c.906G>A p.E302= | Silent (SNP) | VAF 57/208 reads (27%) | catalogued as COSV66153342; called by muse, mutect2, varscan2
- BTBD3 | c.78C>G p.S26= | Silent (SNP) | VAF 111/337 reads (33%) | catalogued as COSV99655830; called by muse, mutect2, varscan2
- CAGE1 | c.627T>G p.A209= (on ENST00000512086; = p.A73= on NM_205864.3) | Silent (SNP) | VAF 84/193 reads (44%) | catalogued as COSV99699648; called by muse, mutect2, varscan2
- CDH16 | c.927G>A p.Q309= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV100233850; called by muse, mutect2, varscan2
- CNTNAP1 | c.1794C>T p.F598= | Silent (SNP) | VAF 37/358 reads (10%) | catalogued as COSV99226309; called by muse, mutect2, varscan2
- DNASE1 | c.513C>T p.D171= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs770091885, COSV55913450; called by muse, mutect2, varscan2
- DRC1 | c.666C>G p.L222= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV56530295, COSV99985338; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1356G>A p.K452= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100349082; called by muse, mutect2, varscan2
- EVPL | c.3024G>A p.K1008= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs1467863589, COSV100044446; called by muse, mutect2, varscan2
- F8 | c.1716C>T p.I572= | Silent (SNP) | VAF 35/220 reads (16%) | catalogued as COSV100811488; called by muse, mutect2, varscan2
- FCGR1A | c.1053G>A p.L351= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100977285; called by mutect2, varscan2
- FUBP1 | c.147A>T p.A49= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99628555; called by muse, mutect2, varscan2
- GDNF | c.225G>A p.L75= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV58478733; called by mutect2, varscan2
- GSE1 | c.189G>A p.A63= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs560356645, COSV53676729, COSV99496470; called by muse, mutect2, varscan2
- HPS1 | c.1029T>A p.P343= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as COSV100282577; called by muse, mutect2, varscan2
- ICA1L | c.1375C>T p.L459= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100841755; called by muse, mutect2, varscan2
- IPP | c.282C>T p.F94= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100739528; called by muse, mutect2, varscan2
- LRP1B | c.9366T>C p.T3122= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1208344270, COSV101256249; called by muse, mutect2, varscan2
- LTB4R | c.207C>G p.L69= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV99350692; called by muse, mutect2, varscan2
- MRPS16 | c.204C>G p.L68= | Silent (SNP) | VAF 24/193 reads (12%) | catalogued as rs369695042, COSV100160548; called by muse, mutect2, varscan2
- MYO7B | c.1503C>T p.L501= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs139033746, COSV101268136; called by muse, mutect2, varscan2
- OR5H14 | c.765C>T p.L255= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs140385435; called by muse, mutect2, varscan2
- OR6M1 | c.894G>A p.L298= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as rs758011795, COSV100484064; called by muse, mutect2, varscan2
- PCDHGA11 | c.2073G>A p.S691= | Silent (SNP) | VAF 20/192 reads (10%) | catalogued as rs1293301567, COSV99537359; called by muse, mutect2, varscan2
- PPP4R2 | c.75G>C p.L25= | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as COSV99865997; called by muse, mutect2, varscan2
- RHOXF1 | c.273G>T p.A91= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as COSV54295561, COSV99483811; called by muse, mutect2, varscan2
- ROBO2 | c.12G>A p.L4= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as rs767861919, COSV100166411; called by muse, mutect2, varscan2
- SETBP1 | c.921G>A p.E307= | Silent (SNP) | VAF 61/136 reads (45%) | catalogued as COSV99953118; called by muse, mutect2, varscan2
- SLC13A2 | c.1203G>A p.L401= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as rs782790385, COSV58992415; called by muse, mutect2, varscan2
- SPATA4 | c.39G>A p.Q13= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV99708945; called by muse, mutect2, varscan2
- TAS1R2 | c.2394C>G p.L798= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV64748070; called by muse, mutect2, varscan2
- TNIP2 | c.255C>T p.A85= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs753505272, COSV100198654; called by muse, mutect2, varscan2
- TRIP12 | c.3315C>T p.F1105= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs1199674882, COSV52265753; called by muse, mutect2, varscan2
- WDR11 | c.2211G>A p.L737= | Silent (SNP) | VAF 25/159 reads (16%) | catalogued as COSV54784952, COSV99676510; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500844 del GGG | 5'Flank (DEL) | VAF 16/39 reads (41%) | catalogued as rs772360578; called by mutect2, pindel, varscan2
- DPP6 | c.*201C>A | 3'UTR (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100125252; called by muse, mutect2, varscan2
- SSPOP | n.7074C>T | RNA (SNP) | VAF 9/82 reads (11%) | catalogued as COSV50486410; called by muse, mutect2, varscan2
